Somatic mutation profile of tumor specimen TCGA-AP-A0LQ-01A (aliquot TCGA-AP-A0LQ-01A-12D-A10B-09) from TCGA case TCGA-AP-A0LQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 59.2 years (21,629 days).
Specimen TCGA-AP-A0LQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6963d0f7-49b4-42d8-ac60-e339d689ebb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LQ-10A (Blood Derived Normal), aliquot TCGA-AP-A0LQ-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8eaa60f-108a-455f-bb3f-f5e6b4a5ae93

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 37, Silent 15, Nonsense Mutation 5, Splice Site 2, In Frame Del 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.3841C>T p.R1281* | Nonsense Mutation (SNP) | VAF 72/235 reads (31%) | catalogued as rs1555910814, COSV54325854; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 49/91 reads (54%) | hotspot (GDC flag); called by pindel, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 60/271 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 39/118 reads (33%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH18A1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.892); catalogued as rs368147360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARL4C | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV60213480; called by mutect2, varscan2
- ARMC4 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs201056632, COSV53462513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMX | c.1547T>C p.M516T | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59590122; called by muse, mutect2, varscan2
- BOLL | c.352+1G>A p.X118_splice | Splice Site (SNP) | VAF 11/335 reads (3%) | catalogued as COSV56573067; called by muse, mutect2
- BRS3 | c.409del p.T137Hfs*2 | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | catalogued as COSV65710659, COSV65710703; called by mutect2, pindel, varscan2
- C11orf42 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV56409464; called by muse, mutect2, varscan2
- CACNA1F | c.5579C>T p.A1860V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs2856748, COSV59902937; called by muse, mutect2
- CAMP | c.316G>A p.G106R (on ENST00000296435; = p.G103R on NM_004345.5) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs758490185, COSV56481725; called by muse, mutect2, varscan2
- CHD3 | c.5684G>A p.R1895H (on ENST00000330494 / NM_001005273.3; = p.R1861H on NM_005852.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1412058339, COSV57872378; called by muse, mutect2, varscan2
- DCC | c.70A>T p.S24C | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as COSV71425330; called by muse, mutect2, varscan2
- DSC3 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs778465727, COSV64571641; called by muse, mutect2
- FAM122C | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs201102053, COSV66194337; called by muse, mutect2, varscan2
- FAXDC2 | c.311C>A p.T104K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV58171256; called by muse, mutect2, varscan2
- GABRA3 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100943100, COSV64795024; called by muse, mutect2, varscan2
- GPRASP1 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.637); catalogued as COSV64354750; called by muse, mutect2, varscan2
- HRNR | c.5903G>C p.G1968A | Missense Mutation (SNP) | VAF 24/489 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as rs1256478911, COSV64253984; called by muse, mutect2
- KRT13 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs781291691, COSV55838986; called by muse, mutect2, varscan2
- LRP1B | c.10471G>A p.D3491N | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.805); catalogued as rs201065495, COSV67185308, COSV67189813; called by muse, mutect2, varscan2
- LRP2 | c.7559A>G p.Y2520C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55540443; called by muse, mutect2, varscan2
- MCRS1 | c.1086+1G>T p.X362_splice | Splice Site (SNP) | VAF 3/22 reads (14%) | catalogued as COSV57789500; called by muse, mutect2
- MLXIP | c.1436A>G p.K479R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.205); catalogued as COSV59833952; called by muse, mutect2, varscan2
- MYCBPAP | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750540313, COSV60405361; called by muse, mutect2, varscan2
- NOS1 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412760885, COSV57606502; called by muse, mutect2, varscan2
- PARD3 | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs372548458; called by muse, mutect2, varscan2
- PCDHAC2 | c.1338A>G p.I446M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53836577; called by muse, mutect2, varscan2
- PCDHGA1 | c.1421T>C p.V474A | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as COSV65294858; called by muse, mutect2, varscan2
- POU3F2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60408442; called by muse, mutect2, varscan2
- PRDM11 | c.149T>G p.V50G (on ENST00000530656 / NM_001359633.1; = p.V16G on NM_001256695.1) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.277); catalogued as COSV55437389; called by muse, mutect2, varscan2
- PTEN | c.136_139dup p.R47Ifs*6 | Frame Shift Ins (INS) | VAF 164/380 reads (43%) | catalogued as COSV64307616; called by mutect2, pindel, varscan2
- RPTN | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 172/569 reads (30%) | catalogued as rs201541838, COSV60166164; called by muse, mutect2, varscan2
- SBNO2 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62318616; called by muse, mutect2
- SLC25A5 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58624818; called by muse, varscan2
- SMC1B | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs768603770, COSV61581080; called by muse, mutect2, varscan2
- SSTR4 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54796798; called by muse, mutect2, varscan2
- TBC1D15 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV59847348; called by muse, mutect2, varscan2
- TINAG | c.1046A>C p.Y349S | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52505354, COSV99449057; called by muse, mutect2, varscan2
- TMC3 | c.2569C>T p.R857* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV63922143; called by muse, mutect2, varscan2
- TNK1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs577697153, COSV61169879; called by muse, mutect2, varscan2
- TTN | c.78816C>A p.C26272* (on ENST00000591111; = p.C18848* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 50/170 reads (29%) | catalogued as COSV59881305; called by muse, mutect2, varscan2
- WDFY1 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51787483; called by muse, mutect2, varscan2
- WEE1 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV55196285; called by muse, mutect2
- ZNF701 | c.1434T>G p.C478W (on ENST00000301093; = p.C412W on NM_018260.3) | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56522984; called by muse, mutect2, varscan2
- ZRSR2 | c.937_937+2del | In Frame Del (DEL) | VAF 30/124 reads (24%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.14784C>T p.S4928= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV60907412; called by muse, mutect2, varscan2
- ASH1L | c.216G>A p.Q72= | Silent (SNP) | VAF 79/241 reads (33%) | catalogued as COSV64205348; called by muse, mutect2, varscan2
- B3GNTL1 | c.285C>T p.Y95= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs375382704, COSV57947884; called by muse, mutect2, varscan2
- BCL9 | c.2523G>T p.L841= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV52340845; called by muse, mutect2
- COPB1 | c.2193C>T p.Y731= | Silent (SNP) | VAF 60/191 reads (31%) | catalogued as rs372930388; called by muse, mutect2, varscan2
- ESAM | c.991T>C p.L331= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1358282848, COSV54033290; called by muse, mutect2, varscan2
- EXOC6 | c.2073C>T p.N691= | Silent (SNP) | VAF 83/312 reads (27%) | catalogued as COSV53319056; called by muse, mutect2, varscan2
- FBXW10 | c.2466G>A p.L822= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV57059182; called by muse, mutect2, varscan2
- GAPVD1 | c.3606G>T p.S1202= (on ENST00000394104; = p.S1211= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as rs181809764, COSV52919976; called by muse, mutect2, varscan2
- HIF3A | c.1737C>T p.D579= (on ENST00000377670 / NM_152795.4; = p.D510= on NM_022462.4) | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs772319491, COSV52195624; called by muse, mutect2, varscan2
- MBP | c.213G>T p.A71= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs769001269, COSV62828479, COSV62828835; called by muse, mutect2, varscan2
- PCDHB13 | c.345C>T p.F115= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV53392971; called by muse, mutect2
- SLC37A1 | c.1335C>T p.S445= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs770452531, COSV61401249; called by muse, mutect2
- TTN | c.49095A>G p.V16365= (on ENST00000591111; = p.V8941= on NM_003319.4) | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV59881326; called by muse, mutect2, varscan2
- UBR4 | c.6087T>C p.C2029= | Silent (SNP) | VAF 64/102 reads (63%) | catalogued as rs1027774363, COSV64382691; called by muse, mutect2, varscan2
